Surgical pathology report (de-identified scan), TCGA case TCGA-06-0211, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0211-02A (Recurrent Tumor).

PATH.NO:

NAME:

MED. REC. NO:

AGE/SEX: M DOB:

SURGERY DATE:

PHYSICIAN:
COPY TO:

RECEIVE DATE:

PATHOLOGICAL DIAGNOSIS:

LEFT PARIETAL BIOPSY: MALIGNANT GLIOMA (GLIOBLASTOMA) AND EFFECTS OF
RADIATION/CHEMOTHERAPY.

ICD-0-3 Recurrence

Operation/Specimen: Left parietal tumor. Necrosis or tumor.

Glioblastoma, multiforme 9440/3

Site - Parietal lobe C71.3

Clinical History and Pre-Op Dx: Hx. of G.B.M. radiation/chemotherapy.

GROSS PATHOLOGY:

SPECIMEN: Left parietal tumor.

GENERAL: The specimen is a 2 x 2 x 1.8 cm. brain parenchyma.

*hw
2/12/15*

INTRAOPERATIVE CONSULTATION, Frozen section diagnosis: Necrosis and
glioma. Frozen section submitted in cassettes 1 and 2, remaining
tissue in cassettes 3,4; additional tissue in 5-8, dural tissue in 9-

MICROSCOPIC: Sections reveal a high grade glioma with
hypercellularity, cellular pleomorphism, mitotic figures and prominent
vascular endothelial hyperplasia. The changes are consistent with
recurrence of glioblastoma. Features associated with radiation and
chemotherapy, including large areas of coagulation necrosis and
sclerotic vessels, are noted. Involvement of the inner surface of the
dura by the tumor is present.

TISSUE COMMITTEE CODE:
BILLING CODES:

Source: NCI Genomic Data Commons file 9f879ee3-9d1f-4c6e-9ed8-a73a8ee97b38 (TCGA-06-0211.528DED4E-C801-4F67-BB1E-62470B39B41E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).